Gene-level copy-number profile of tumor specimen C3N-08896-01 from CPTAC case C3N-08896, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 56.9 years (20,765 days).
Specimen C3N-08896-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9e32658e-f835-4f05-a10f-c4297a557b53.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-08896-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/9a535666-45c8-4164-9d43-f820ac7d8086

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 182; copy number 1: 15,246; copy number 2: 33,516; copy number 3: 8,875; copy number 4: 491; copy number 6: 53; copy number 7: 24.

Homozygous deletions (total copy number 0; autosomes only): 174 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:13,555,001–13,555,694, 1 gene: BRWD1P1.
- chr3:36,169,767–36,170,448, 1 gene: RFC3P1.
- chr4:12,312,588–12,312,690, 1 gene: RNU6-578P.
- chr4:35,487,812–35,496,003, 2 genes: SEC63P2, RNU6-573P.
- chr4:40,426,119–40,492,024, 2 genes (within-gene range 0–1): AC098869.2, AC098869.1.
- chr4:184,254,509–184,382,416, 5 genes: AC079080.1, RN7SL28P, MYL12BP2, LINC02363, LINC02362.
- chr4:187,995,771–188,121,634, 4 genes: ZFP42, TRIML2, AC108073.2, RNU6-173P.
- chr5:60,021,249–60,033,020, 1 gene (within-gene range 0–2): AC034234.1.
- chr6:162,568,379–164,348,644, 18 genes (within-gene range 0–1): KRT8P44, PACRG, AL590286.1, AL590286.2, PACRG-AS2, AL137182.1, PACRG-AS3, PACRG-AS1, AL031121.1, CAHM, QKI, AL445307.1, AL078602.1, AL137005.1, RN7SL366P, Z97205.2, Z97205.1, AL358972.1.
- chr6:165,279,664–165,309,605, 1 gene: C6orf118.
- chr8:27,171,914–27,210,783, 1 gene: AC090150.1.
- chr9:4,984,390–5,235,304, 16 genes: JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4.
- chr9:18,573,306–18,651,450, 2 genes (within-gene range 0–1): MIR3152, RN7SKP258.
- chr9:20,999,509–21,031,640, 1 gene: HACD4.
- chr13:48,389,567–48,444,704, 2 genes (within-gene range 0–2): LPAR6, Metazoa_SRP.
- chr14:22,040,594–22,552,156, 99 genes (within-gene range 0–1) (broad region; genes not listed).
- chr14:23,630,115–23,792,236, 5 genes: DHRS2, AL160237.1, BRD7P1, AL160237.3, RN7SKP205.
- chr14:43,274,824–43,300,595, 2 genes: TUBBP3, HNRNPUP1.
- chr16:78,495,926–78,553,296, 4 genes (within-gene range 0–1): AC046158.1, AC046158.4, AC046158.2, AC046158.3.
- chr18:60,519,841–60,526,156, 2 genes: MRPS5P4, AC010928.3.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–3): RPS10P2.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–3): AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 77 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:74,073,353–78,544,188, 77 genes, copy number 6–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12,959. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
